Somatic mutation profile of tumor specimen MMRF_2760_1_BM_CD138pos (aliquot MMRF_2760_1_BM_CD138pos_T1_KHS5U_L15712) from MMRF case MMRF_2760, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2760_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52ae3caf-50e0-45bd-ac13-1f6ea7dce2e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2760_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2760_1_PB_WBC_C3_KHS5U_L15756; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d36f081-1786-4756-b37a-087c946e160e

The open-access MAF lists 228 somatic variants for this specimen: 85 protein-altering or splice-affecting, 22 silent, 121 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, 3'UTR 61, Silent 22, Intron 20, 5'UTR 15, 5'Flank 13, RNA 7, Nonsense Mutation 7, 3'Flank 5, Frame Shift Ins 3, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.106A>T p.R36W | Missense Mutation (SNP) | VAF 33/37 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418001; called by muse, mutect2, varscan2
- AHI1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760220297, COSV55623563, COSV55626363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 73/79 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58190428; called by muse, mutect2, varscan2
- ASCL4 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV60816968; called by muse, mutect2, varscan2
- CDH10 | c.2182C>A p.P728T | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52572979, COSV52594377; called by muse, mutect2, varscan2
- CUL3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV52366993; called by muse, mutect2, varscan2
- EVPL | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 156/312 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs373420968; called by muse, mutect2, varscan2
- FOXJ2 | c.1249A>G p.N417D | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs766267392; called by muse, mutect2, varscan2
- GABRG1 | c.792dup p.D265* | Frame Shift Ins (INS) | VAF 60/150 reads (40%) | catalogued as rs772301203; called by mutect2, varscan2
- GPR149 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as rs749204115, COSV67667215; called by muse, mutect2, varscan2
- IGHD3-9 | c.6A>T p.L2F | Missense Mutation (SNP) | VAF 68/70 reads (97%) | catalogued as rs372964417; called by muse, varscan2
- IGHV2-70 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1567837962; called by muse, mutect2, varscan2
- IGLV3-19 | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs546247992; called by muse, mutect2, varscan2
- IGLV7-46 | c.217A>C p.S73R | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs756073973; called by muse, varscan2
- IGLV7-46 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as rs531624748; called by muse, varscan2
- IGLV7-46 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749946995; called by muse, varscan2
- IKZF4 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100009457, COSV56271810; called by muse, mutect2, varscan2
- METTL21C | c.388G>C p.A130P | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1178608385; called by muse, mutect2, varscan2
- MOGAT3 | c.669-1G>T p.X223_splice | Splice Site (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99777219; called by muse, mutect2, varscan2
- NEFH | c.2402C>A p.S801Y | Missense Mutation (SNP) | VAF 90/175 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV60218797; called by muse, mutect2, varscan2
- NFRKB | c.68C>T p.T23M (on ENST00000446488 / NM_001143835.2; = p.T36M on NM_006165.3) | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs369458984; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- OTOGL | c.2272T>C p.C758R (on ENST00000547103; = p.C749R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509175; called by muse, mutect2, varscan2
- PIWIL2 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 61/145 reads (42%) | catalogued as rs1275364551; called by muse, mutect2, varscan2
- PRDM2 | c.4906C>T p.R1636W | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373292998; called by muse, mutect2, varscan2
- RLF | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs776618617, COSV65652089; called by muse, mutect2, varscan2
- RNF224 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1252343966; called by muse, mutect2, varscan2
- RYR2 | c.7968A>T p.K2656N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV63671371; called by muse, mutect2, varscan2
- SCN11A | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56565806, COSV56572876; called by muse, mutect2, varscan2
- SLC22A9 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 224/502 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs756160377, COSV54166826; called by muse, mutect2, varscan2
- TAMALIN | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs1334116555; called by muse, mutect2, varscan2
- TTLL8 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs374245397; called by muse, mutect2, varscan2
- UBE2QL1 | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV67717122; called by muse, mutect2, varscan2
- UBR5 | c.8138G>A p.W2713* | Nonsense Mutation (SNP) | VAF 44/129 reads (34%) | catalogued as COSV55283867; called by muse, mutect2, varscan2
- ARSG | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AXDND1 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- BAX | c.77T>A p.L26* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- BIN1 | c.441_442insC p.V148Rfs*21 | Frame Shift Ins (INS) | VAF 49/131 reads (37%) | called by mutect2, pindel, varscan2
- CCDC39 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CCER1 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CEP192 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2
- CFAP44 | c.4474A>G p.K1492E | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL4A1 | c.4598T>A p.M1533K | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CUTC | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- DUXA | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- DYRK1A | c.1451A>C p.D484A | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ENPP1 | c.1400A>T p.Y467F | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GCKR | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 162/320 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GDPD4 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 224/446 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HMGCLL1 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HSPB11 | c.352A>T p.I118F | Missense Mutation (SNP) | VAF 116/224 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IGKV4-1 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT tolerated (0.27); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IGLV3-21 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 84/90 reads (93%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, varscan2
- ITM2C | c.232T>G p.Y78D | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- JRKL | c.-166C>A | Splice Region (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- KMT2A | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, varscan2
- KRT34 | c.1226dup p.C411Lfs*10 | Frame Shift Ins (INS) | VAF 78/203 reads (38%) | called by mutect2, pindel, varscan2
- LNX1 | c.650G>A p.R217K (on ENST00000263925 / NM_001126328.3; = p.R121K on NM_032622.2) | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRFN2 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 145/235 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- LRIG2 | c.3173T>A p.I1058N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LRRTM3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MYH13 | c.3950A>C p.E1317A | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MYO1H | c.2176G>T p.G726* | Nonsense Mutation (SNP) | VAF 80/197 reads (41%) | called by muse, mutect2, varscan2
- NDRG2 | c.218T>G p.L73R (on ENST00000298687 / NM_001354570.1; = p.L59R on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OSMR | c.2057G>T p.C686F | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PAX2 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPM1G | c.1532C>A p.A511E | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RBP3 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- S1PR4 | c.502_521del p.L168Afs*17 | Frame Shift Del (DEL) | VAF 83/208 reads (40%) | called by mutect2, pindel, varscan2
- SLC18A2 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SLIT2 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN4 | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TENM1 | c.6950G>C p.C2317S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.243); called by muse, mutect2
- TIPIN | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TNC | c.4699G>A p.G1567R | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TRAF3 | c.1323C>A p.Y441* | Nonsense Mutation (SNP) | VAF 139/145 reads (96%) | called by muse, mutect2, varscan2
- TTC17 | c.3030+1G>T p.X1010_splice | Splice Site (SNP) | VAF 145/332 reads (44%) | called by muse, mutect2, varscan2
- UNC13C | c.2996T>A p.V999E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- USP32 | c.1058T>G p.L353W | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- USP8 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN1 | c.2617G>T p.V873F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB7C | c.828C>G p.D276E | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ZNF367 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 106/192 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ZNF382 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- A1BG | c.1281C>A p.I427= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs771083874; called by muse, mutect2, varscan2
- BTAF1 | c.1461A>T p.T487= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- CEP97 | c.1798T>C p.L600= | Silent (SNP) | VAF 83/180 reads (46%) | called by muse, mutect2, varscan2
- CLCNKA | c.375G>A p.E125= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- DNAH1 | c.1410C>G p.L470= | Silent (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- EXTL1 | c.618G>A p.P206= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as rs768099208, COSV65338459; called by muse, mutect2, varscan2
- IGLV3-16 | c.189G>A p.V63= | Silent (SNP) | VAF 90/96 reads (94%) | catalogued as rs375149658; called by muse, varscan2
- IGLV3-16 | c.252C>T p.S84= | Silent (SNP) | VAF 82/90 reads (91%) | called by muse, varscan2
- IGLV5-45 | c.360C>T p.S120= | Silent (SNP) | VAF 144/355 reads (41%) | called by muse, varscan2
- KIF21B | c.3222T>C p.H1074= | Silent (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- KLK15 | c.144C>T p.G48= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs371448196; called by muse, mutect2, varscan2
- MAGI2 | c.624T>G p.T208= | Silent (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- MCCC2 | c.675C>T p.A225= | Silent (SNP) | VAF 104/324 reads (32%) | called by muse, mutect2, varscan2
- NEB | c.12114C>T p.D4038= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV99426211; called by muse, mutect2, varscan2
- NPDC1 | c.138G>A p.L46= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as rs369916050; called by muse, mutect2, varscan2
- PSD2 | c.2265C>G p.G755= | Silent (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1173C>A p.A391= | Silent (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- SOGA3 | c.2256C>T p.D752= | Silent (SNP) | VAF 110/209 reads (53%) | called by muse, mutect2, varscan2
- TELO2 | c.396G>A p.R132= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1175338853; called by muse, mutect2
- TMEM132B | c.48G>A p.G16= | Silent (SNP) | VAF 85/163 reads (52%) | catalogued as rs770029944; called by muse, mutect2, varscan2
- TRIM75P | c.243C>A p.L81= | Silent (SNP) | VAF 100/231 reads (43%) | called by muse, mutect2, varscan2
- ZNF653 | c.6G>A p.A2= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ABHD6 | c.119+1916A>G | Intron (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- AC011525.1 | n.877G>A | RNA (SNP) | VAF 107/231 reads (46%) | catalogued as rs1315439249; called by muse, mutect2, varscan2
- ADAMTS3 | c.*1601C>T | 3'UTR (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- ADH1B | c.*1795C>T | 3'UTR (SNP) | VAF 8/13 reads (62%) | catalogued as rs1005806982; called by muse, mutect2
- ADH5P5 | chr5:23980065 A>C | 5'Flank (SNP) | VAF 145/290 reads (50%) | called by muse, mutect2, varscan2
- AFDN | c.2037+463G>T | Intron (SNP) | VAF 53/97 reads (55%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38441G>A | Intron (SNP) | VAF 71/153 reads (46%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+29545G>T | Intron (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- ARL13B | c.-246T>G | 5'UTR (SNP) | VAF 120/278 reads (43%) | called by muse, mutect2, varscan2
- ARSB | chr5:78985833 A>C | 5'Flank (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- ASB4 | chr7:95485914 T>C | 5'Flank (SNP) | VAF 91/208 reads (44%) | called by muse, mutect2, varscan2
- BARD1 | c.*223C>A | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020964 A>T | 5'Flank (SNP) | VAF 80/164 reads (49%) | catalogued as rs555966767, COSV55847805; called by muse, mutect2, varscan2
- BCL7A | chr12:122021519 A>C | 5'Flank (SNP) | VAF 107/238 reads (45%) | called by muse, mutect2, varscan2
- C10orf90 | c.-65C>A | 5'UTR (SNP) | VAF 89/174 reads (51%) | called by muse, mutect2, varscan2
- C16orf72 | c.*65A>G | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- C1orf226 | c.*1021G>A | 3'UTR (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- C1orf229 | n.2108G>A | RNA (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- C2orf49 | c.*2165A>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- C5orf64 | n.513-42330A>T | Intron (SNP) | VAF 70/209 reads (33%) | called by muse, mutect2, varscan2
- C8orf34 | c.607+97C>T | Intron (SNP) | VAF 81/187 reads (43%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81950013 A>T | 3'Flank (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- CASD1 | c.*565T>A | 3'UTR (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- CCNI | c.244-76T>C | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2
- CCNL1 | chr3:157160450 T>C | 5'Flank (SNP) | VAF 85/206 reads (41%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65882428 A>G | 3'Flank (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- CEACAM19 | chr19:44671417 G>A | 5'Flank (SNP) | VAF 34/57 reads (60%) | called by muse, mutect2, varscan2
- CENPP | c.*4762T>G | 3'UTR (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2, varscan2
- CEP41 | c.*2290A>T | 3'UTR (SNP) | VAF 50/81 reads (62%) | called by muse, mutect2, varscan2
- CFL1 | chr11:65858499 T>C | 5'Flank (SNP) | VAF 279/640 reads (44%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018665 G>A | 3'Flank (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- COLGALT2 | c.*1480T>C | 3'UTR (SNP) | VAF 64/140 reads (46%) | called by muse, mutect2
- CST11 | chr20:23452970 T>C | 5'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, varscan2
- CYB561A3 | c.*919C>G | 3'UTR (SNP) | VAF 124/278 reads (45%) | called by muse, mutect2, varscan2
- DGKB | c.*3216T>C | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- DHX40P1 | n.1120T>G | RNA (SNP) | VAF 71/169 reads (42%) | called by muse, mutect2, varscan2
- DNAAF4 | c.-112C>A | 5'UTR (SNP) | VAF 75/162 reads (46%) | catalogued as rs1423410936; called by muse, mutect2, varscan2
- DPP8 | c.*3381T>G | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- EHD3 | c.*1450C>G | 3'UTR (SNP) | VAF 85/181 reads (47%) | called by muse, mutect2, varscan2
- EMSY | c.*1066T>G | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- EPHA10 | c.850+232T>G | Intron (SNP) | VAF 24/56 reads (43%) | called by muse, varscan2
- F13A1 | c.*519G>T | 3'UTR (SNP) | VAF 64/86 reads (74%) | called by muse, mutect2, varscan2
- FZD6 | c.*885T>G | 3'UTR (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.-46G>C | 5'UTR (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2
- GYG2 | c.*1135C>T | 3'UTR (SNP) | VAF 54/57 reads (95%) | called by muse, mutect2, varscan2
- H4C9 | c.*56C>G | 3'UTR (SNP) | VAF 149/256 reads (58%) | catalogued as rs188731680, COSV62889813; called by muse, mutect2, varscan2
- HECA | c.-298A>C | 5'UTR (SNP) | VAF 40/93 reads (43%) | catalogued as rs1335158462; called by muse, mutect2, varscan2
- HMGA2 | c.198+63T>C | Intron (SNP) | VAF 71/144 reads (49%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.198+13194C>A | Intron (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- HOXB4 | c.-18G>T | 5'UTR (SNP) | VAF 202/399 reads (51%) | called by muse, mutect2, varscan2
- HSPH1 | c.*261T>A | 3'UTR (SNP) | VAF 157/168 reads (93%) | called by muse, mutect2, varscan2
- IGF2 | c.-73G>A | 5'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- IGLJ6 | chr22:22919800 A>T | 3'Flank (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- IGLL5 | c.*167A>G | 3'UTR (SNP) | VAF 135/139 reads (97%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.88T>A | RNA (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.-11A>C | 5'UTR (SNP) | VAF 77/140 reads (55%) | called by muse, mutect2, varscan2
- INHBA | c.*1065T>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- INPP5E | c.*875C>G | 3'UTR (SNP) | VAF 86/187 reads (46%) | called by muse, mutect2, varscan2
- JDP2 | chr14:75473330 C>A | 3'Flank (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- KCNB1 | c.*3793C>T | 3'UTR (SNP) | VAF 52/88 reads (59%) | called by muse, mutect2, varscan2
- KLHL21 | c.1500+581dup | Intron (INS) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- KMT2A | c.-20C>T | 5'UTR (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- KMT2A | c.-19T>A | 5'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- LINC00174 | n.3740C>T | RNA (SNP) | VAF 14/30 reads (47%) | catalogued as rs574826771; called by muse, mutect2, varscan2
- MAPK14 | c.*87C>A | 3'UTR (SNP) | VAF 65/218 reads (30%) | called by muse, mutect2, varscan2
- MDM4 | c.*5520T>C | 3'UTR (SNP) | VAF 7/9 reads (78%) | called by muse, varscan2
- ME2 | c.*1164G>A | 3'UTR (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- MINDY2 | c.*1921G>C | 3'UTR (SNP) | VAF 107/272 reads (39%) | called by muse, mutect2, varscan2
- NAF1 | c.-139A>C | 5'UTR (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- NR2F1 | c.*204A>G | 3'UTR (SNP) | VAF 30/66 reads (45%) | catalogued as rs932605101; called by muse, mutect2, varscan2
- NSD2 | c.*486T>C | 3'UTR (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- NYAP2 | c.*482C>T | 3'UTR (SNP) | VAF 33/85 reads (39%) | catalogued as rs1298758582; called by muse, mutect2, varscan2
- OLFM4 | c.*834_*835insGATTAGAACTGA | 3'UTR (INS) | VAF 46/70 reads (66%) | called by mutect2, varscan2
- P4HTM | chr3:48989889 G>A | 5'Flank (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- PADI2 | c.*1909G>C | 3'UTR (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- PCDH11X | c.*3892C>A | 3'UTR (SNP) | VAF 82/84 reads (98%) | called by mutect2, varscan2
- PCDH7 | c.*183T>A | 3'UTR (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- PCGF3 | c.*4351A>G | 3'UTR (SNP) | VAF 80/146 reads (55%) | called by muse, mutect2, varscan2
- PCMTD1 | c.706+4164A>G | Intron (SNP) | VAF 34/68 reads (50%) | catalogued as rs1422689895; called by muse, mutect2, varscan2
- PHF21B | c.*563C>T | 3'UTR (SNP) | VAF 48/109 reads (44%) | catalogued as rs987254792; called by muse, mutect2, varscan2
- PHF8 | c.-53_-51del | 5'UTR (DEL) | VAF 110/130 reads (85%) | called by pindel, varscan2
- PHKG2 | c.272-61C>T | Intron (SNP) | VAF 41/79 reads (52%) | catalogued as rs1008628297, COSV60311350; called by muse, mutect2, varscan2
- PIK3R2 | c.1808+46G>C | Intron (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- PPP4R2 | c.*1322T>G | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- PRPF40B | c.3+112G>C | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as rs1216329629; called by muse, mutect2, varscan2
- PSMB2 | c.*331T>C | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4512C>T | Intron (SNP) | VAF 42/72 reads (58%) | catalogued as rs1189757972; called by mutect2, varscan2
- RANBP17 | c.489+28G>C | Intron (SNP) | VAF 84/189 reads (44%) | called by muse, mutect2, varscan2
- RASSF5 | c.*2135A>C | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- RIT1 | c.*463T>G | 3'UTR (SNP) | VAF 101/191 reads (53%) | called by muse, mutect2, varscan2
- RNF130 | c.*1060C>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- RNGTT | c.*2281C>A | 3'UTR (SNP) | VAF 52/104 reads (50%) | catalogued as rs1335351032; called by muse, mutect2, varscan2
- RPGRIP1 | c.587+75G>T | Intron (SNP) | VAF 23/25 reads (92%) | called by muse, varscan2
- RUNX1T1 | c.*4770T>A | 3'UTR (SNP) | VAF 35/72 reads (49%) | catalogued as rs1390729661; called by muse, mutect2, varscan2
- SAMD5 | c.*5182G>T | 3'UTR (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- SCGB1C2 | c.*80T>A | 3'UTR (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- SEMA3E | c.*781dup | 3'UTR (INS) | VAF 47/115 reads (41%) | catalogued as rs148414428; called by mutect2, varscan2
- SERAC1 | c.*700T>G | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- SETD1B | c.*2049C>G | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175830 T>G | 5'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- SIDT2 | chr11:117176046 G>A | 5'Flank (SNP) | VAF 127/260 reads (49%) | catalogued as rs551709376; called by muse, mutect2, varscan2
- SPA17 | c.-71G>C | 5'UTR (SNP) | VAF 58/144 reads (40%) | called by muse, varscan2
- SPRED1 | c.*2272T>C | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- SRF | c.*687T>A | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- SYT12 | c.*1116G>A | 3'UTR (SNP) | VAF 70/143 reads (49%) | catalogued as rs1435754809; called by muse, mutect2, varscan2
- TFCP2L1 | c.*3375C>A | 3'UTR (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- TMEFF2 | c.439+127C>A | Intron (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.*2896C>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- TNKS | c.*3273T>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs1011779509; called by muse, mutect2, varscan2
- TPRX2P | n.778G>A | RNA (SNP) | VAF 120/270 reads (44%) | catalogued as rs767105051; called by muse, mutect2, varscan2
- TRAM2 | c.-48T>G | 5'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- TRIM45 | chr1:117122103 A>G | 5'Flank (SNP) | VAF 69/177 reads (39%) | called by muse, mutect2, varscan2
- TSPYL1 | c.*1543T>A | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- TUSC1 | c.*1195C>T | 3'UTR (SNP) | VAF 60/145 reads (41%) | called by muse, mutect2, varscan2
- UBE2U | c.*51G>A | 3'UTR (SNP) | VAF 152/354 reads (43%) | catalogued as rs999382125; called by muse, mutect2, varscan2
- VPS41 | c.*887T>G | 3'UTR (SNP) | VAF 85/173 reads (49%) | called by muse, mutect2, varscan2
- XBP1 | c.*748T>A | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- Z85994.1 | n.256G>A | RNA (SNP) | VAF 89/203 reads (44%) | catalogued as rs1197742345; called by muse, mutect2, varscan2
- ZBBX | c.2138-9543T>G | Intron (SNP) | VAF 47/77 reads (61%) | called by muse, mutect2, varscan2
- ZNF134 | c.-183G>A | 5'UTR (SNP) | VAF 41/90 reads (46%) | catalogued as rs1476471062; called by muse, mutect2, varscan2
- ZNF385D | c.*2137C>T | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
